Surgical pathology report (de-identified scan), TCGA case TCGA-J4-A67O, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site ABS - Lahey Clinic, specimen TCGA-J4-A67O-01A (Primary Tumor).

[page 1 of 4]
MRN

Gender

M

Name

Date Of Birth

Encounter Number

COPY ONLY DO NOT FILE

SURGICAL PATHOLOGY

Time Collected

Time Received

Time Reported

Order Number

Ordering Provider

Status

Final

Results

Final

Source of Specimen

- A. RIGHT PELVIC LYMPH NODES-
- B. LEFT PELVIC LYMPH NODES-
- C. TISSUE ANTERIOR TO PROSTATE-
- D. PROSTATE GLAND-

FINAL DIAGNOSIS:

- A. RIGHT PELVIC LYMPH NODES-
ONE LYMPH NODE, NO TUMOR SEEN.
- B. LEFT PELVIC LYMPH NODES-
ONE LYMPH NODE, NO TUMOR SEEN.
- C. TISSUE ANTERIOR TO PROSTATE-
MATURE ADIPOSE TISSUE, NO TUMOR SEEN.
- D. PROSTATE GLAND-
ADENOCARCINOMA OF PROSTATE. NO EXTRAPROSTATIC EXTENSION SEEN.

ICD-0-3
adenocarcinoma, NOS 8140/3
Site: prostate, NOS C61.9

pw
11/7/14

TUMOR SITE: BILATERAL, MOSTLY IN APICAL ZONE.

SPECIMEN TYPE: RADICAL PROSTATECTOMY.

WEIGHT: 44.0 GRAMS. SIZE: 4.0 x 4.0 x 3.5 CM.

GLEASON SCORE (PRIMARY + SECONDARY PATTERN): 3 + 4 = 7/10.

SEVERITY IN EXTENT OF TUMOR: 30-50% of examined tissue involvement.

DOMINANT NODULE (AT LEAST 1 CM IN SIZE): NOT PRESENT.

Prepared for:

[page 2 of 4]
TNM STAGE: pT2c, pN0, pMX.

LYMPHATIC (SMALL VESSEL) INVASION: NOT SEEN.

PERINEURAL INVASION: IS PRESENT.

NO TUMOR SEEN IN SEMINAL VESICLES.

NO TUMOR SEEN AT SPECIMEN MARGINS.

Signature

Case Clinical Information
PROSTATE CANCER

Gross Description

- A. Received in formalin labeled with the patient's name and "right pelvic lymph nodes" is a yellow fibrofatty tissue fragment measuring 3 x 2 x 0.3 cm. The fat is trimmed and one probable lymph node is grossly identified which measures 1.5 x 1 x 0.3 cm. Bisected, wrapped and entirely submitted in A1.
- B. Received in formalin labeled with the patient's name and "left pelvic lymph nodes" is a yellow fibrofatty tissue fragment measuring 3 x 2 x 1 cm. The fat is trimmed and one probable lymph node is grossly identified which measures 1.5 x 1 x 0.3 cm. Bisected, wrapped and entirely submitted in B1.
- C. Received in formalin labeled with the patient's name and "tissue anterior to prostate" is a yellow fibrofatty tissue fragment measuring 5 x 4 x 0.5 cm. No lymph nodes are grossly identified. Submitted complete in C1-C7.
- D. Received in formalin labeled "prostate gland" is a radical prostatectomy specimen which includes a 44 gram prostate gland with attached seminal vesicles and vas deferentia. The prostate gland measures 4 x 4 x 3.5 cm and has a shaggy capsule that is disrupted at the bladder resection margin and has been previously inked black on the left and blue on the right. The right seminal vesicle measures 3 x 1.5 cm. The right vas measures 2.5 x 0.5 cm. The left seminal vesicle measures 3 x 1.5 cm. The left vas measures 3 x 0.5 cm. The inferior prostate is sectioned transversely, removed from the rest of the specimen and sectioned from anterior to posterior following the plane of the urethra. The remaining gland is serially sectioned transversely and shows a firm, focally nodular parenchyma. The seminal vesicles and vasa deferentia show no abnormalities. Representative sections submitted as follows: inferior prostate

Prepared for

[page 3 of 4]
demonstrating apical margin submitted entirely anterior to posterior in D1-D6; bladder resection margin in D7, D8; complete section of mid gland anterior in D9, D10; posterior in D11, D12; complete section of upper third of gland, anterior in D13, D14; posterior in D15, D16; remainder of the posterior gland entirely submitted in D17-D22; right seminal vesicle and vas deferens in D23; left seminal vesicle and vas deferens in D24. There are two additional cassettes for research labeled "normal" and "tumor".

Physicians

Procedure

A. AA ROUTINE H&E X1 BLOCK
H&E X1
B. AA ROUTINE H&E X1 BLOCK
H&E X1
C. AA ROUTINE H&E X1 BLOCK.1
H&E X1
C. AA ROUTINE H&E X1 BLOCK.2
H&E X1
C. AA ROUTINE H&E X1 BLOCK.3
H&E X1
C. AA ROUTINE H&E X1 BLOCK.4
H&E X1
C. AA ROUTINE H&E X1 BLOCK.5
H&E X1
C. AA ROUTINE H&E X1 BLOCK.6
H&E X1
C. AA ROUTINE H&E X1 BLOCK.7
H&E X1
D. AA ROUTINE H&E X1 BLOCK.1
H&E X1
D. AA ROUTINE H&E X1 BLOCK.2
H&E X1
D. AA ROUTINE H&E X1 BLOCK.3
H&E X1
D. AA ROUTINE H&E X1 BLOCK.4
H&E X1
D. AA ROUTINE H&E X1 BLOCK.5
H&E X1 A RECUTS
D. AA ROUTINE H&E X1 BLOCK.6
H&E X1
D. AA ROUTINE H&E X1 BLOCK.7
H&E X1
D. AA ROUTINE H&E X1 BLOCK.8

Prepared for

[page 4 of 4]
H&E X1
D. AA ROUTINE H&E X1 BLOCK.9
H&E X1
D. AA ROUTINE H&E X1 BLOCK.10
H&E X1
D. AA ROUTINE H&E X1 BLOCK.11
H&E X1
D. AA ROUTINE H&E X1 BLOCK.12
H&E X1
D. AA ROUTINE H&E X1 BLOCK.13
H&E X1
D. AA ROUTINE H&E X1 BLOCK.14
H&E X1
D. AA ROUTINE H&E X1 BLOCK.15
H&E X1
D. AA ROUTINE H&E X1 BLOCK.16
H&E X1
D. AA ROUTINE H&E X1 BLOCK.17
H&E X1
D. AA ROUTINE H&E X1 BLOCK.18
H&E X1
D. AA ROUTINE H&E X1 BLOCK.19
H&E X1
D. AA ROUTINE H&E X1 BLOCK.20
H&E X1
D. AA ROUTINE H&E X1 BLOCK.21
H&E X1
D. AA ROUTINE H&E X1 BLOCK.22
H&E X1
D. AA ROUTINE H&E X1 BLOCK.23
H&E X1
D. AA ROUTINE H&E X1 BLOCK.24
H&E X1

Prepared for _____

Source: NCI Genomic Data Commons file 7b4dbbea-d493-4057-be93-e210e7e92574 (TCGA-J4-A67O.BF98B941-3DEB-46EB-803D-4A4AF49F529E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).